Somatic mutation profile of tumor specimen TARGET-10-PATMVH-09A (aliquot TARGET-10-PATMVH-09A-01D) from TARGET case TARGET-10-PATMVH, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.4 years (6,724 days).
Specimen TARGET-10-PATMVH-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3404f930-3602-44b8-b029-cb5aea403321.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATMVH-10A (Blood Derived Normal), aliquot TARGET-10-PATMVH-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81404650-7df5-4b99-b118-d105981cedb9

The open-access MAF lists 18 somatic variants for this specimen: 10 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Ins 1, In Frame Ins 1, Frame Shift Del 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 31/146 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.2172A>T p.R724S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.661); catalogued as COSV52748940; called by muse, mutect2, varscan2
- ARHGEF10L | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs780477750, COSV51443352; called by muse, varscan2
- CDKN1B | c.586del p.R196Vfs*29 | Frame Shift Del (DEL) | VAF 22/53 reads (42%) | catalogued as rs775142813, COSV57432010; called by mutect2, pindel, varscan2
- CLTC | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV52251683; called by muse, mutect2, varscan2
- LVRN | c.2749A>T p.S917C | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); catalogued as COSV63498878; called by muse, mutect2
- OR2M5 | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.58); catalogued as rs138582176, COSV63547279; called by muse, varscan2
- POR | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782151568, COSV67518893; called by muse, mutect2, varscan2
- SI | c.887dup p.L296Ffs*4 | Frame Shift Ins (INS) | VAF 17/39 reads (44%) | catalogued as rs769103567, COSV52271231; called by mutect2, varscan2
- RBM27 | c.2503_2504insGGGAGG p.L834_E835insGE | In Frame Ins (INS) | VAF 18/50 reads (36%) | called by mutect2, pindel, varscan2
- DDR1 | c.1560C>T p.Y520= | Silent (SNP) | VAF 14/162 reads (9%) | catalogued as rs1039650854; called by muse, mutect2
- KCNS3 | c.681C>T p.I227= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as rs752619752; called by muse, mutect2, varscan2
- PTPRK | c.4206C>T p.V1402= (on ENST00000368215 / NM_001291984.2; = p.V1403= on NM_002844.4) | Silent (SNP) | VAF 99/215 reads (46%) | catalogued as rs374115534; called by muse, mutect2, varscan2
- PWWP3B | c.2062C>A p.R688= | Silent (SNP) | VAF 30/32 reads (94%) | catalogued as COSV100531532; called by muse, mutect2, varscan2
- RGS21 | c.189A>C p.A63= | Silent (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- SPHKAP | c.4971C>T p.V1657= (on ENST00000392056 / NM_001142644.2; = p.V1628= on NM_030623.3) | Silent (SNP) | VAF 79/205 reads (39%) | catalogued as rs749944414, COSV60872408; called by muse, mutect2, varscan2
- PICK1 | c.41+49C>T | Intron (SNP) | VAF 104/244 reads (43%) | catalogued as rs1206672733; called by muse, mutect2, varscan2
- TRAV6 | chr14:21769080 ins TGG | 3'Flank (INS) | VAF 27/112 reads (24%) | called by mutect2, pindel*, varscan2
